Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DI, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DI-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure:
Left thoracotomy mediastinal mass

Pre-Operative Diagnosis:
As below

Post-Operative Diagnosis:
As below

Specimen Received:
A: Mediastinal mass
B: Pericardial fat and thymus

Addendum Report

Addendum Comment

A representative portion of this case was sent for special study for addendum is created to report the findings of the special study. The report is scanned into the patient's electronic medical record . This

ASSAY DESCRIPTION

THYMOMA[TM] gene expression assay for thymoma tumors is a proprietary assay which uses RT-PCR to determine the expression levels of a 13 gene panel (4 controls) in primary tumor tissue samples. The THYMOMA classification is calculated from the gene expression results as compared to results of a training set of patients with known outcomes.

RESULTS

Decision Diagnosis-Thymoma Class = 1

Patients with a Class 1 molecular signature have a low risk of experiencing near term (within 10 years) clinical metastasis.

Final Pathologic Diagnosis:

A. Mediastinal mass, resection:
Thymoma, AB type

Specimen: Mediastinal mass
Procedure: Subtotal thymectomy
Specimen integrity: Intact
Specimen weight: 130 g
Tumor size: 8.2 cm (greatest dimension)
Histologic type: Thymoma, AB type
Tumor extension: Not identified

Margins:

Margin involved by tumor

ICD-O-3
Thymoma, type AB malignant, 8582/E
Site: ^{cell}Thymus C37.9
^{path}Mediastinum, anterior C38.1
JSD 6/18/14

[page 2 of 3]
Specify margin: External inked margin (no orientation provided)

Treatment effect: Not applicable
Lymph-vascular invasion: Not identified
Regional lymph nodes: Not examined

Pathologic Staging for Thymomas (Modified Masaoka Stage): Stage I: Grossly and microscopically encapsulated

Implants/distant metastasis: Cannot be assessed

Additional pathologic Findings: None

B. Pericardial fat and thymus, resection:
Benign thymic and fibroadipose tissue.
Negative for malignancy.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Part A is received in formalin and additionally labeled, "mediastinal mass (anterior)" and consists of a single portion of yellow-tan lobular fatty tissue with overall dimensions of 10.0 x 7.2 x 3.8 cm. The specimen has a weight of 130 g. The external surface of the specimen is inked in black. The specimen is remarkable for a lobular mass within the fatty tissue with dimensions of 8.2 x 5.5 x 4.5 cm. A portion of this mass has been banked with the Tissue bank. Sectioning through the mass reveals a tan-white, lobular fleshy cut surface. There are no areas of hemorrhage or necrosis identified. The mass is well circumscribed and does not appear to infiltrate into the surrounding fatty tissue. The remaining fatty tissue is yellow-tan and lobular. There are no additional masses identified. Representative sections of the mass are submitted in cassettes A1-A8.

Part B is additionally labeled, "pericardial fat and thymus" and consists of an aggregate of yellow-tan fatty tissue with dimensions of 6.0 x 4.1 x 1.4 cm. A search of the fatty tissue reveals a lobular, yellow-tan fatty cut surface. There are no distinct masses identified. Representative sections are submitted in cassettes B1 through B3.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

[page 3 of 3]
Surgical Pathology Report
* Procedure/Addenda present *

Taken: DOB: Gender: F

Source: NCI Genomic Data Commons file 24d07005-fc3e-43e2-9304-1166e78fbf38 (TCGA-X7-A8DI.F54717FD-81E8-4AFE-8D51-D4B82D5F3060.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).